Gene-level copy-number profile of specimen HCM-BROD-0103-C71-85B from HCMI case HCM-BROD-0103-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,295 days).
Specimen HCM-BROD-0103-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4df45a62-d0a9-4943-8932-58bf434c2c56.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0103-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,380 have no estimate.
https://portal.gdc.cancer.gov/files/77026745-39e3-4fb2-b158-ab15eb7d80e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,602; copy number 2: 48,455; copy number 3: 3,768; copy number 4: 81; copy number 5: 254; copy number 6: 10; copy number 7: 54; copy number 8: 13; copy number 9: 4; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 337 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:190,077–262,873, 5 genes, copy number 5: SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2.
- chr12:389,273–442,642, 1 gene, copy number 5 (within-gene range 1–5): CCDC77.
- chr12:2,812,622–4,774,184, 51 genes, copy number 5 (within-gene range 1–5): ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1.
- chr12:5,388,589–6,866,632, 58 genes, copy number 5: AC007848.1, NTF3, ANO2, AC137627.1, VWF, RN7SL69P, AC005845.1, CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P, AC125494.3, COPS7A, AC125494.2, MLF2, PTMS, LAG3, RN7SL380P, CD4, GPR162, P3H3, GNB3, CDCA3, USP5.
- chr12:22,609,228–24,584,549, 14 genes, copy number 5–12 (within-gene range 1–12): AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1.
- chr12:24,810,024–24,967,504, 5 genes, copy number 7: BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2.
- chr12:26,335,352–26,833,194, 1 gene, copy number 8 (within-gene range 3–8): ITPR2.
- chr12:26,623,369–29,381,189, 55 genes, copy number 7–8: AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2.
- chr12:58,394,596–58,395,138, 1 gene, copy number 5: AC025578.1.
- chr19:50,188,186–52,171,533, 146 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,602. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
